Somatic mutation profile of tumor specimen MMRF_2383_1_BM_CD138pos (aliquot MMRF_2383_1_BM_CD138pos_T1_KHS5U_L11079) from MMRF case MMRF_2383, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,675 days).
Specimen MMRF_2383_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f53369a-5f13-43a5-9d42-313292ee6ba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2383_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2383_1_PB_Whole_C2_KHS5U_L11080; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d72c01cf-1296-41d3-b2ee-b31294bf3866

The open-access MAF lists 322 somatic variants for this specimen: 124 protein-altering or splice-affecting, 44 silent, 154 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, 3'UTR 71, Silent 44, Intron 44, 5'UTR 12, Nonsense Mutation 11, 5'Flank 10, RNA 10, 3'Flank 7, Splice Site 6, Frame Shift Del 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PIM1 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100998754, COSV65164441, COSV65164484; called by muse, mutect2, varscan2
- RYR1 | c.14129+1G>A p.X4710_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs142929172, COSV62110710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs782165228, COSV59509829; called by muse, mutect2, varscan2
- AGPS | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1218864725; called by muse, mutect2, varscan2
- AGPS | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs749653767; called by muse, mutect2, varscan2
- CACNG7 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV55817075; called by muse, mutect2, varscan2
- CCDC189 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV100079520, COSV60311608; called by muse, mutect2
- CHP2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766912448; called by muse, mutect2, varscan2
- CNNM1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140364515; called by muse, mutect2, varscan2
- DPP6 | c.1244C>T p.T415M (on ENST00000377770 / NM_001364500.2; = p.T353M on NM_001936.5) | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59630861; called by muse, mutect2, varscan2
- EGR1 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs1393783755, COSV53520677; called by muse, varscan2
- EHD1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778829881, COSV57733628; called by muse, mutect2, varscan2
- EIF2S3B | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs765480041; called by muse, varscan2
- FPGT-TNNI3K | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs192259069, COSV58547076; called by muse, mutect2, varscan2
- GCNT3 | c.847_849del p.K283del | In Frame Del (DEL) | VAF 221/396 reads (56%) | catalogued as rs777839068; called by pindel, varscan2
- H2BC10 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV100010316; called by muse, mutect2, varscan2
- H2BC14 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV104411752; called by muse, mutect2, varscan2
- HMX3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.182); catalogued as rs201882443; called by muse, mutect2, varscan2
- IGHV1-3 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs561032078; called by muse, varscan2
- IGHV2-70 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 84/92 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs377473012; called by muse, varscan2
- IGHV2-70 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs544365977; called by muse, varscan2
- IGHV6-1 | c.170A>C p.N57T | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.213); catalogued as rs782239968; called by muse, varscan2
- IGKV1-8 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 96/102 reads (94%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369059950; called by muse, mutect2, varscan2
- IGLL5 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as rs566521884, COSV73250915, COSV73251180; called by muse, varscan2
- IGLV3-1 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 70/76 reads (92%) | catalogued as rs373828762; called by muse, mutect2, varscan2
- IGLV4-3 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs188425943; called by muse, mutect2, varscan2
- IL25 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs375340039; called by muse, mutect2, varscan2
- KCNG1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs17791076; called by muse, mutect2, varscan2
- LAMA5 | c.7757-4G>A | Splice Region (SNP) | VAF 26/70 reads (37%) | catalogued as rs368921445; called by muse, mutect2, varscan2
- MAPK4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1428180163; called by muse, mutect2, varscan2
- MPDU1 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 139/270 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV51467558; called by muse, mutect2, varscan2
- MST1R | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 172/538 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.292); catalogued as COSV56569702; called by muse, mutect2, varscan2
- NAV3 | c.4961G>T p.G1654V | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV57065824; called by muse, mutect2, varscan2
- NF1 | c.821T>G p.L274R | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62220272; called by muse, mutect2, varscan2
- NLRP5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 193/298 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs770891485, COSV66764352; called by muse, mutect2, varscan2
- NOL9 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1427375828; called by muse, varscan2
- NUDT7 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs370570737; called by muse, mutect2, varscan2
- OXR1 | c.697C>A p.L233M (on ENST00000442977 / NM_001198532.1; = p.L232M on NM_018002.3) | Missense Mutation (SNP) | VAF 75/135 reads (56%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); catalogued as rs376686752; called by muse, mutect2, varscan2
- PRDM16 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs572604983, COSV54603745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD3 | c.1462del p.E488Kfs*18 | Frame Shift Del (DEL) | VAF 86/235 reads (37%) | catalogued as COSV58971482; called by mutect2, pindel, varscan2
- SEC14L5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316449, COSV52039575; called by muse, mutect2, varscan2
- SGIP1 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs373240389; called by muse, mutect2, varscan2
- SLC1A7 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.195); catalogued as rs542658976; called by muse, mutect2, varscan2
- SLC38A10 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV66102461; called by muse, mutect2, varscan2
- SMG7 | c.1164-1G>A p.X388_splice | Splice Site (SNP) | VAF 53/108 reads (49%) | catalogued as COSV61631440; called by muse, mutect2, varscan2
- SPATA31D1 | c.4537A>C p.S1513R | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61194296; called by muse, mutect2
- SPINK5 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.491); catalogued as COSV56253642; called by muse, mutect2, varscan2
- SPTAN1 | c.7195G>A p.E2399K | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63986169; called by muse, mutect2, varscan2
- SRGAP2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1553352011; called by muse, mutect2, varscan2
- SRGAP2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs782218322; called by muse, mutect2, varscan2
- SYT16 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs755013221, COSV70857964; called by muse, mutect2, varscan2
- TCL1A | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68085861; called by muse, varscan2
- TMEM39B | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV60378997; called by muse, mutect2, varscan2
- TPRX1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs750996738; called by muse, mutect2, varscan2
- TRAPPC2L | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1272548985, COSV51935603; called by muse, mutect2, varscan2
- TTN | c.52564C>G p.L17522V (on ENST00000591111; = p.L10098V on NM_003319.4) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | PolyPhen probably damaging (0.996); catalogued as COSV100634765; called by muse, mutect2, varscan2
- ZIC1 | c.999G>C p.K333N | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV51556884, COSV51558790; called by muse, mutect2, varscan2
- ZIC2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1418541472; called by muse, mutect2
- ZNFX1 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.629); catalogued as COSV65575509, COSV65576985; called by muse, mutect2, varscan2
- ADGRG7 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 107/248 reads (43%) | called by muse, mutect2, varscan2
- ASB10 | c.1006C>A p.Q336K (on ENST00000420175 / NM_001142459.2; = p.Q321K on NM_080871.4) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ATAD2B | c.3430T>C p.W1144R | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATP2B2 | c.3158G>A p.W1053* (on ENST00000352432; = p.W1019* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 81/121 reads (67%) | called by muse, varscan2
- ATXN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CDH9 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CEP55 | c.1258_1259del p.E420Kfs*15 | Frame Shift Del (DEL) | VAF 91/256 reads (36%) | called by pindel, varscan2
- CNTNAP4 | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL6A5 | c.3776A>G p.K1259R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CSK | c.962T>G p.L321R | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSTL1 | c.168_177del p.N57Tfs*8 | Frame Shift Del (DEL) | VAF 57/203 reads (28%) | called by mutect2, pindel, varscan2
- DNAH11 | c.1211C>A p.S404* | Nonsense Mutation (SNP) | VAF 77/176 reads (44%) | called by muse, mutect2, varscan2
- DNAH11 | c.3140A>G p.E1047G | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EIF2AK3 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ELP6 | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 245/404 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FANK1 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GORASP1 | c.436-2A>G p.X146_splice | Splice Site (SNP) | VAF 77/237 reads (32%) | called by muse, mutect2, varscan2
- H2BC21 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HGF | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HNRNPA1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICAM1 | c.719_742del p.D240_E247del | In Frame Del (DEL) | VAF 72/360 reads (20%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.701); called by muse, varscan2
- IGHV3-72 | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGLV4-60 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 104/121 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- IL31 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ISY1-RAB43 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 270/427 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KCNAB1 | c.345A>C p.Q115H (on ENST00000490337 / NM_172160.3; = p.Q104H on NM_003471.3) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MALT1 | c.2363C>A p.S788* | Nonsense Mutation (SNP) | VAF 111/268 reads (41%) | called by muse, mutect2, varscan2
- MAN2A2 | c.2719-6C>T | Splice Region (SNP) | VAF 76/239 reads (32%) | called by muse, mutect2, varscan2
- NLGN1 | c.877A>T p.I293L | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP7 | c.2653T>A p.C885S (on ENST00000340844 / NM_206828.3; = p.C857S on NM_139176.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2
- NOL9 | c.261_265del p.S88Dfs*48 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2
- OSBPL10 | c.281+1_281+3del p.X94_splice | Splice Site (DEL) | VAF 18/31 reads (58%) | called by mutect2, pindel, varscan2
- PARD3B | c.1562C>G p.T521S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHB | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2
- PKD1L3 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPFIA3 | c.2674C>A p.L892I | Missense Mutation (SNP) | VAF 116/204 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PRDM16 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, varscan2
- PTBP2 | c.816C>G p.Y272* (on ENST00000426398 / NM_001300986.2; = p.Y264* on NM_021190.4) | Nonsense Mutation (SNP) | VAF 56/145 reads (39%) | called by muse, mutect2, varscan2
- RABGEF1 | c.1253T>G p.L418* (on ENST00000439720 / NM_001287061.2; = p.L405* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- RAET1E | c.346+1G>A p.X116_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2
- RALGAPA2 | c.1829A>C p.N610T | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SBSN | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 243/399 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- SEL1L2 | c.1553C>A p.A518E | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SEMA3C | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- SHC4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 269/408 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- SKIV2L | c.3167A>G p.H1056R | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPIN4 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 71/74 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.7333G>T p.E2445* | Nonsense Mutation (SNP) | VAF 134/195 reads (69%) | called by muse, mutect2, varscan2
- TACC1 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TANC2 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D16 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCL1A | c.70T>G p.F24V | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, varscan2
- TERB2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- TLR2 | c.718dup p.S240Ffs*7 | Frame Shift Ins (INS) | VAF 37/114 reads (32%) | called by mutect2, pindel, varscan2
- TMEM115 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TMEM267 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 166/381 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TRAV19 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- UBE2A | c.45-1G>A p.X15_splice | Splice Site (SNP) | VAF 59/62 reads (95%) | called by muse, varscan2
- UBE2A | c.45G>A p.R15= | Splice Region (SNP) | VAF 60/63 reads (95%) | called by muse, varscan2
- UNC45B | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- USP28 | c.2213A>G p.H738R | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2
- ZNF629 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ACSBG1 | c.1090C>T p.L364= | Silent (SNP) | VAF 102/312 reads (33%) | catalogued as rs757842128, COSV99357896; called by muse, mutect2, varscan2
- ADAMTS8 | c.735G>A p.T245= | Silent (SNP) | VAF 64/107 reads (60%) | catalogued as rs751276351; called by muse, mutect2, varscan2
- AKT2 | c.1194C>T p.S398= | Silent (SNP) | VAF 70/108 reads (65%) | catalogued as rs761556498, COSV60908562; called by muse, mutect2, varscan2
- ANKRD11 | c.5325C>A p.A1775= | Silent (SNP) | VAF 140/265 reads (53%) | called by muse, mutect2, varscan2
- CCDC8 | c.267G>A p.P89= | Silent (SNP) | VAF 133/219 reads (61%) | catalogued as rs776591696; called by muse, mutect2, varscan2
- CDH7 | c.90A>C p.S30= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- CDK13 | c.813C>G p.R271= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- CFAP47 | c.807T>C p.H269= | Silent (SNP) | VAF 78/81 reads (96%) | called by muse, mutect2, varscan2
- CIT | c.4774C>T p.L1592= | Silent (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- COL6A1 | c.1986G>C p.V662= | Silent (SNP) | VAF 50/90 reads (56%) | called by muse, mutect2, varscan2
- CORO7 | c.1399C>T p.L467= | Silent (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- DNHD1 | c.13641G>A p.P4547= | Silent (SNP) | VAF 72/234 reads (31%) | catalogued as rs1416794310; called by muse, mutect2, varscan2
- DSC1 | c.1845C>T p.A615= | Silent (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- ETV1 | c.1011C>T p.L337= | Silent (SNP) | VAF 84/185 reads (45%) | catalogued as rs1383607683, COSV99624411; called by muse, mutect2, varscan2
- EYS | c.3507A>G p.P1169= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs750490503; called by muse, mutect2, varscan2
- F5 | c.6420C>A p.G2140= | Silent (SNP) | VAF 75/177 reads (42%) | catalogued as rs759734191; called by muse, mutect2, varscan2
- FAM102A | c.81G>A p.V27= | Silent (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- FEV | c.210C>T p.G70= | Silent (SNP) | VAF 52/92 reads (57%) | catalogued as rs1266897411, COSV55386849; called by muse, mutect2, varscan2
- FJX1 | c.402G>A p.P134= | Silent (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- H3C2 | c.180G>A p.E60= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as rs766249159; called by muse, mutect2, varscan2
- HECW1 | c.2238C>T p.F746= | Silent (SNP) | VAF 132/237 reads (56%) | catalogued as rs765972904, COSV67827286; called by muse, mutect2, varscan2
- HHEX | c.342G>A p.L114= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- KLHL21 | c.690C>T p.R230= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1433807790; called by muse, mutect2, varscan2
- LAG3 | c.42G>A p.P14= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs746963580; called by muse, mutect2, varscan2
- MAFA | c.981C>T p.G327= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- MAP2K7 | c.1155G>A p.T385= | Silent (SNP) | VAF 72/213 reads (34%) | catalogued as rs775374156; called by muse, mutect2, varscan2
- MUC5AC | c.15066G>A p.S5022= | Silent (SNP) | VAF 94/316 reads (30%) | catalogued as rs542220678, COSV64369480; called by muse, varscan2
- MYOD1 | c.840G>A p.P280= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as rs766804536; called by muse, mutect2, varscan2
- NCAM1 | c.1704G>A p.E568= (on ENST00000316851 / NM_181351.5; = p.E558= on NM_000615.7) | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- NECAP1 | c.78C>T p.A26= | Silent (SNP) | VAF 87/179 reads (49%) | catalogued as rs367812288; called by muse, mutect2, varscan2
- NFKBIZ | c.2058C>T p.N686= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs776484306; called by muse, mutect2, varscan2
- NUTF2 | c.90C>T p.G30= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs746153759, COSV54646466; called by muse, mutect2, varscan2
- OR5M8 | c.621T>C p.S207= | Silent (SNP) | VAF 73/290 reads (25%) | catalogued as COSV59116399; called by muse, mutect2, varscan2
- SETD2 | c.813G>A p.L271= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV57441101; called by muse, mutect2, varscan2
- SHANK1 | c.4104G>A p.S1368= | Silent (SNP) | VAF 31/44 reads (70%) | called by muse, mutect2, varscan2
- SLIT2 | c.2175T>C p.S725= | Silent (SNP) | VAF 104/206 reads (50%) | called by muse, mutect2, varscan2
- SPATA5 | c.2187G>A p.L729= | Silent (SNP) | VAF 112/235 reads (48%) | called by muse, mutect2, varscan2
- TIMM22 | c.564G>A p.A188= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs774655559, COSV52143659; called by muse, mutect2, varscan2
- TRIM37 | c.2727C>T p.D909= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs1376737679; called by muse, mutect2, varscan2
- UBA6 | c.1839T>C p.S613= | Silent (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- UNC45B | c.141G>T p.R47= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV52096930; called by mutect2, varscan2
- UNCX | c.699C>T p.S233= | Silent (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- UTP20 | c.6882C>T p.Y2294= | Silent (SNP) | VAF 101/238 reads (42%) | catalogued as rs767216294, COSV55371783; called by muse, mutect2, varscan2
- ZNF366 | c.690G>A p.E230= | Silent (SNP) | VAF 130/262 reads (50%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1516+790T>C | Intron (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- AC103993.1 | n.351dup | RNA (INS) | VAF 65/156 reads (42%) | catalogued as rs1011679380; called by mutect2, pindel, varscan2
- AC114741.1 | n.324A>C | RNA (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- ACADVL | c.138+44C>T | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- AGAP1 | c.1646-21686T>A | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- ALOX5 | c.1272+111G>A | Intron (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- ANKRD49P3 | n.542G>T | RNA (SNP) | VAF 58/133 reads (44%) | catalogued as rs911681670; called by muse, mutect2, varscan2
- ANP32E | chr1:150236142 C>T | 5'Flank (SNP) | VAF 111/240 reads (46%) | called by muse, mutect2, varscan2
- ARSB | chr5:78985485 G>A | 5'Flank (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ATF4 | c.-565G>A | 5'UTR (SNP) | VAF 97/183 reads (53%) | called by muse, mutect2, varscan2
- ATOH1 | c.*136T>C | 3'UTR (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- ATP5F1AP2 | n.289G>T | RNA (SNP) | VAF 82/160 reads (51%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 58/122 reads (48%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BHLHE40 | c.*80G>A | 3'UTR (SNP) | VAF 212/319 reads (66%) | called by muse, mutect2, varscan2
- BRD2 | c.-1305+276G>A | Intron (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- CA12 | c.*1710C>G | 3'UTR (SNP) | VAF 37/182 reads (20%) | catalogued as rs554261389; called by muse, mutect2, varscan2
- CALM1 | c.-85G>A | 5'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- CBX8 | c.*1747G>A | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- CCND1 | c.*444T>G | 3'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- CCNT2 | c.*893G>A | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-34050del | Intron (DEL) | VAF 16/40 reads (40%) | catalogued as rs1217159096; called by mutect2, pindel, varscan2
- CD36 | c.1199+123T>C | Intron (SNP) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- CDC14A | c.*10A>T | 3'UTR (SNP) | VAF 113/253 reads (45%) | called by muse, mutect2, varscan2
- CDH15 | c.663+123C>A | Intron (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- CENATAC | chr11:118997087 G>T | 5'Flank (SNP) | VAF 18/56 reads (32%) | called by muse, varscan2
- CENATAC | chr11:118997143 G>C | 5'Flank (SNP) | VAF 16/58 reads (28%) | catalogued as rs1259413375; called by muse, varscan2
- CENATAC | chr11:118997239 G>A | 5'Flank (SNP) | VAF 28/91 reads (31%) | called by muse, varscan2
- CEP295 | c.5851-99G>C | Intron (SNP) | VAF 62/188 reads (33%) | called by muse, varscan2
- CHRD | c.*100C>A | 3'UTR (SNP) | VAF 59/93 reads (63%) | called by muse, mutect2, varscan2
- CLCN3 | c.161-19893C>G | Intron (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- CLIC4 | c.*2039_*2063del | 3'UTR (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- COBLL1 | c.344+138del | Intron (DEL) | VAF 12/20 reads (60%) | catalogued as rs201476254; called by mutect2, varscan2
- COCH | c.928+132G>A | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- COX15 | c.*580T>C | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- CREB1 | chr2:207603476 T>G | 3'Flank (SNP) | VAF 23/48 reads (48%) | catalogued as rs577610531; called by muse, mutect2, varscan2
- DIRC1 | n.849del | RNA (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- DSCAM | c.*1510A>G | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- DST | c.4297-2637C>T | Intron (SNP) | VAF 56/125 reads (45%) | catalogued as rs765074149; called by muse, mutect2, varscan2
- DTWD1 | c.*1572_*1573del | 3'UTR (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- DTX1 | c.-73C>T | 5'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- EEA1 | c.*1532C>T | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- EPB41L1 | c.*3091_*3118del | 3'UTR (DEL) | VAF 42/174 reads (24%) | called by mutect2, pindel
- EPHA5 | c.*2289T>G | 3'UTR (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894115 A>T | 3'Flank (SNP) | VAF 23/55 reads (42%) | catalogued as rs1390226788; called by muse, mutect2, varscan2
- FAM98B | chr15:38485338 C>T | 3'Flank (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- FBXL21P | n.911T>A | RNA (SNP) | VAF 69/155 reads (45%) | called by muse, mutect2, varscan2
- FEZ2 | c.979+32A>C | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- FGL2 | c.*768G>C | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- FIGN | c.*737del | 3'UTR (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- FLRT3 | c.*766A>G | 3'UTR (SNP) | VAF 90/187 reads (48%) | called by muse, mutect2, varscan2
- FMR1 | c.199-30G>T | Intron (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2852G>A | 3'UTR (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- FREM2 | c.*3841C>A | 3'UTR (SNP) | VAF 36/100 reads (36%) | catalogued as rs1413838209; called by muse, mutect2, varscan2
- FTO | c.*6727T>A | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- GABRB2 | c.1191+75del | Intron (DEL) | VAF 17/40 reads (43%) | called by mutect2, varscan2
- GABRB3 | c.*335A>G | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, varscan2
- GAD2 | c.*34+898C>T | Intron (SNP) | VAF 34/78 reads (44%) | catalogued as rs927799255, COSV52163142; called by muse, mutect2, varscan2
- GALK1 | c.-1C>T | 5'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs1217882815; called by muse, mutect2, varscan2
- GPD1L | c.*2269A>C | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- GRM5 | c.661+38133A>G | Intron (SNP) | VAF 119/187 reads (64%) | called by muse, mutect2, varscan2
- GRM7-AS3 | n.72+4368T>A | Intron (SNP) | VAF 134/210 reads (64%) | called by muse, mutect2, varscan2
- H2BC17 | c.*2C>T | 3'UTR (SNP) | VAF 108/230 reads (47%) | catalogued as rs1391207987; called by muse, mutect2
- HERPUD1 | c.431+74A>G | Intron (SNP) | VAF 18/28 reads (64%) | catalogued as rs1334000590, COSV55861371; called by mutect2, varscan2
- HMGA2 | c.249+21136G>T | Intron (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- HTR1F | c.*547A>G | 3'UTR (SNP) | VAF 67/96 reads (70%) | called by muse, mutect2, varscan2
- HTR2C | c.349+31584C>A | Intron (SNP) | VAF 122/130 reads (94%) | called by muse, mutect2, varscan2
- IGLL5 | c.-114C>T | 5'UTR (SNP) | VAF 27/32 reads (84%) | catalogued as COSV73250997, COSV73251237; called by muse, mutect2, varscan2
- ISCU | c.419-608G>A | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ISL1 | c.-50C>T | 5'UTR (SNP) | VAF 64/143 reads (45%) | called by muse, mutect2, varscan2
- ISLR2 | c.*1759G>A | 3'UTR (SNP) | VAF 103/161 reads (64%) | called by muse, mutect2, varscan2
- ITGBL1 | c.-148C>T | 5'UTR (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- KAZN | c.1222+1805G>A | Intron (SNP) | VAF 40/82 reads (49%) | catalogued as rs1261076751; called by muse, mutect2, varscan2
- KCNE4 | c.*2274del | 3'UTR (DEL) | VAF 7/19 reads (37%) | catalogued as rs561998983; called by mutect2, pindel, varscan2
- KCNMB2 | c.*1480dup | 3'UTR (INS) | VAF 29/94 reads (31%) | catalogued as rs201642652; called by mutect2, varscan2
- KCTD5 | c.*707T>C | 3'UTR (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- KIR3DP1 | n.371G>A | RNA (SNP) | VAF 60/101 reads (59%) | catalogued as rs1036362749; called by muse, mutect2, varscan2
- KRR1 | c.*4278dup | 3'UTR (INS) | VAF 16/49 reads (33%) | catalogued as rs767945471; called by mutect2, pindel, varscan2
- KRTAP9-2 | c.*124C>A | 3'UTR (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- LEPR | c.2674-1307A>C | Intron (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- LINC02076 | n.665C>G | RNA (SNP) | VAF 178/789 reads (23%) | called by muse, varscan2
- LINC02076 | n.747T>C | RNA (SNP) | VAF 122/604 reads (20%) | catalogued as rs531041485; called by muse, varscan2
- LIPT2 | c.*106C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- LTA | c.100-37G>A | Intron (SNP) | VAF 78/188 reads (41%) | called by muse, varscan2
- LTA4H | chr12:96035638 G>A | 5'Flank (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- LTB | c.163-22C>T | Intron (SNP) | VAF 176/400 reads (44%) | called by muse, varscan2
- LTB | c.163-40C>G | Intron (SNP) | VAF 191/438 reads (44%) | catalogued as rs115773593; called by muse, varscan2
- LTB | c.163-99A>C | Intron (SNP) | VAF 178/382 reads (47%) | called by muse, varscan2
- LTB | c.163-156A>T | Intron (SNP) | VAF 98/181 reads (54%) | catalogued as rs532177689; called by muse, mutect2, varscan2
- LY9 | chr1:160796144 G>T | 5'Flank (SNP) | VAF 56/136 reads (41%) | catalogued as rs773012606; called by muse, mutect2, varscan2
- MGLL | c.*355G>T | 3'UTR (SNP) | VAF 61/108 reads (56%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851262 del CCATCCACTCCAG | 5'Flank (DEL) | VAF 33/127 reads (26%) | called by pindel, varscan2
- MORC4 | c.*18C>T | 3'UTR (SNP) | VAF 112/116 reads (97%) | called by muse, mutect2, varscan2
- MPP2 | c.*631G>A | 3'UTR (SNP) | VAF 29/70 reads (41%) | catalogued as rs577682602; called by muse, mutect2, varscan2
- MPP7 | c.*253C>A | 3'UTR (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- MSMO1 | c.*1020T>C | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- NEDD4 | c.*2006C>G | 3'UTR (SNP) | VAF 44/75 reads (59%) | catalogued as rs1309768448; called by muse, mutect2, varscan2
- NPTXR | c.*2038A>G | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- NTRK3 | c.*11871C>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- NTRK3 | c.*11636C>T | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- NUTF2 | c.*106G>A | 3'UTR (SNP) | VAF 43/85 reads (51%) | catalogued as rs550044079, COSV99534574; called by muse, mutect2, varscan2
- OFCC1 | n.2176C>A | RNA (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2
- ONECUT1 | c.*277C>A | 3'UTR (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- OVCH1 | c.2280+52A>C | Intron (SNP) | VAF 117/267 reads (44%) | called by muse, mutect2, varscan2
- PAWR | c.*4220G>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- PAX2 | c.-309C>T | 5'UTR (SNP) | VAF 60/108 reads (56%) | called by muse, mutect2, varscan2
- PAX6 | c.142-229T>G | Intron (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- PELI1 | c.*1030G>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- PFKFB3 | c.*2238G>A | 3'UTR (SNP) | VAF 34/63 reads (54%) | catalogued as rs1466805580; called by muse, mutect2, varscan2
- PHF14 | c.*57T>G | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, varscan2
- PHF20 | c.256-1922C>A | Intron (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- PIGQ | chr16:569533 G>T | 5'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PPM1M | c.*449C>T | 3'UTR (SNP) | VAF 87/156 reads (56%) | called by muse, mutect2, varscan2
- PPP1CB | c.185-300T>C | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- PROSER1 | c.-473G>A | 5'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- PTCH2 | chr1:44819962 G>A | 3'Flank (SNP) | VAF 23/60 reads (38%) | catalogued as rs567045658; called by muse, mutect2, varscan2
- PUS7L | c.*1344A>G | 3'UTR (SNP) | VAF 27/56 reads (48%) | catalogued as rs978206891; called by muse, mutect2, varscan2
- PWWP3A | chr19:1376569 G>A | 3'Flank (SNP) | VAF 28/72 reads (39%) | catalogued as rs772499034; called by muse, mutect2, varscan2
- RANBP17 | c.*941C>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- RASGEF1A | chr10:43196064 ins A | 3'Flank (INS) | VAF 56/125 reads (45%) | catalogued as rs1051880077; called by mutect2, varscan2
- RBFA | c.*2143C>G | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- RBM24 | c.169-411C>G | Intron (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100553190, COSV59004829; called by muse, mutect2, varscan2
- RBM43 | c.*2267A>G | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-27C>G | Intron (SNP) | VAF 41/84 reads (49%) | catalogued as rs965402043; called by muse, mutect2, varscan2
- REPS1 | c.*104A>G | 3'UTR (SNP) | VAF 98/204 reads (48%) | called by muse, mutect2, varscan2
- RFX4 | c.*88C>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- RGS7BP | c.-17T>G | 5'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.-149G>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs1196104683; called by muse, mutect2, varscan2
- S100A16 | c.*501T>C | 3'UTR (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- SAXO1 | c.-7C>A | 5'UTR (SNP) | VAF 143/223 reads (64%) | catalogued as COSV101000163; called by muse, mutect2, varscan2
- SCOC | c.181+260G>T | Intron (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- SCUBE1 | c.727+2665C>T | Intron (SNP) | VAF 48/98 reads (49%) | catalogued as rs1355208964, COSV51811566; called by muse, mutect2, varscan2
- SEMA3D | c.976+15T>G | Intron (SNP) | VAF 97/188 reads (52%) | called by muse, mutect2, varscan2
- SEMA6D | c.*2069G>A | 3'UTR (SNP) | VAF 87/283 reads (31%) | catalogued as rs1050442058, COSV100317380; called by muse, mutect2, varscan2
- SEPTIN6 | c.*666G>A | 3'UTR (SNP) | VAF 20/24 reads (83%) | called by muse, mutect2, varscan2
- SF3A2 | c.355+138C>T | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- SH3TC2 | c.52+605G>T | Intron (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- SLC11A2 | c.271-320C>T | Intron (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- SLC5A8 | c.*1717T>C | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.*233A>C | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- SOCS2 | c.*328A>T | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276190 G>T | 3'Flank (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- TEDDM1 | c.*692A>C | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- TMEM120A | c.*245G>T | 3'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- TMEM132D | c.*1201T>G | 3'UTR (SNP) | VAF 95/199 reads (48%) | catalogued as rs1036464716; called by muse, mutect2, varscan2
- TMEM260 | c.941+22dup | Intron (INS) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- TMEM86A | c.*1719G>C | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- TMSB4X | chrX:12975445 T>G | 5'Flank (SNP) | VAF 63/70 reads (90%) | called by muse, mutect2, varscan2
- TMTC1 | c.*4525G>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- TNC | c.*456A>G | 3'UTR (SNP) | VAF 94/153 reads (61%) | called by muse, mutect2, varscan2
- TRIAP1 | c.*365C>T | 3'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- UNC45B | c.*1662G>T | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- UPF2 | c.*1215dup | 3'UTR (INS) | VAF 30/68 reads (44%) | called by mutect2, pindel, varscan2
- WLS | c.*132G>A | 3'UTR (SNP) | VAF 52/116 reads (45%) | catalogued as rs933997792; called by muse, mutect2, varscan2
- ZFPM2 | c.*530T>C | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
